Gene-level copy-number profile of tumor specimen TCGA-D6-6517-01A from TCGA case TCGA-D6-6517, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 59.7 years (21,791 days).
Specimen TCGA-D6-6517-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.410eb344-47ff-40ad-9d21-5b075e597c41.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-6517-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c1a6d600-9e5f-47bc-ad5d-8ac2a2e39a7e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 10,053; copy number 2: 43,549; copy number 3: 3,462; copy number 4: 2,245; copy number 5: 96; copy number 6: 194; copy number 7: 205.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-6517-01A-11D-1869-01): tumor purity 0.44, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:49,794,246–49,796,097, 1 gene: AC025040.2.
- chr15:49,877,299–49,883,525, 1 gene: AC025040.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 495 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–4,440,259, 96 genes, copy number 5 (broad region; genes not listed).
- chr5:17,601,882–19,234,487, 28 genes, copy number 6: AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223, RPL36AP21, SNORD81, RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15.
- chr5:38,556,765–38,671,216, 1 gene, copy number 6 (within-gene range 4–6): LIFR-AS1.
- chr5:38,682,070–45,895,970, 110 genes, copy number 6 (broad region; genes not listed).
- chr7:45,268,681–51,729,716, 84 genes, copy number 6–7 (within-gene range 1–7) (broad region; genes not listed).
- chr7:51,773,836–57,837,046, 176 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,674. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
